Gene-level copy-number profile of tumor specimen TCGA-CN-A640-01A from TCGA case TCGA-CN-A640, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 40.4 years (14,758 days).
Specimen TCGA-CN-A640-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.2e24761c-532a-493f-a467-b3297e3ee0b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A640-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf7059c0-ce84-4cfd-a15d-fe4a31b236c4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,107; copy number 3: 4,390; copy number 4: 43,875; copy number 5: 1,636; copy number 6: 4,145; copy number 8: 1,534; copy number 9: 1; copy number 11: 6; copy number 25: 48; copy number 42: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A640-01A-21D-A30D-01): tumor purity 0.31, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 133 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–50,860,020, 6 genes, copy number 11: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1.
- chr7:54,656,358–57,473,559, 126 genes, copy number 25–42 (within-gene range 6–42) (broad region; genes not listed).
- chr9:9,090,898–9,091,245, 1 gene, copy number 9: RPS26P3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
